Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-A8FP, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-A8FP-01A (Primary Tumor).

[page 1 of 2]
Collection Date:

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIS, DISSECTION -
EIGHTEEN (18) LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/18).

PART 2: LYMPH NODES, LEFT PELVIS, DISSECTION -
TWENTY-THREE (23) LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/23).

PART 3: FAT PAD, ANTERIOR, EXCISION-
BENIGN FIBROADIPOSE TISSUE, NO TUMOR PRESENT.

*Pur TSS - Gleason is 5+4=9
BCR*

PART 4: PROSTATE, BILATERAL SEMINAL VESICLES AND DISTAL VASA DEFERENTIA, RADICAL PROSTATECTOMY -
A. INVASIVE PROSTATIC ADENOCARCINOMA, ACINAR TYPE, GLEASON SCORE 3 + 5 = 8, WITH A TERTIARY 4 COMPONENT.

- B. CARCINOMA INVOLVES BOTH RIGHT AND LEFT LOBES AND HAS A MAXIMAL NODULAR DIAMETER OF 1.5 cm (slide 4Y).
- C. CARCINOMA INVOLVES APPROXIMATELY 10% OF THE EXAMINED PROSTATE VOLUME.
- D. CARCINOMA IS ORGAN CONFINED AND SHOWS NO EVIDENCE OF EXTRACAPSULAR EXTENSION.
- E. BILATERAL SEMINAL VESICLES AND DISTAL VASA DEFERENTIA ARE FREE OF CARCINOMA.
- F. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- G. PERINEURAL INVASION IS IDENTIFIED.
- H. ANGIOLYMPHATIC INVASION IS NOT IDENTIFIED.
- I. HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- J. TNM PATHOLOGIC STAGE (AJCC 7th EDITION): pT2c N0 MX.
- K. TNM HISTOLOGIC GRADE = G3-4.
- L. BACKGROUND PROSTATIC PARENCHYMA WITH FOCAL GLANDULAR ATROPHY.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA: PSA value: 10.3
INVASIVE CA IDENTIFIED?: Yes
TUMOR HISTOLOGY: Ductal adenocarcinoma
PRIMARY GLEASON GRADE: 3
SECONDARY GLEASON GRADE: 5
GLEASON SUM SCORE: 8
GLEASON 4/5 PERCENTAGE: 15%
WEIGHT OF PROSTATE: 43.17gm
TUMOR SIZE: Maximum dimension: 2.5 cm
LOBE LATERALITY: Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR: 5 - 25%
MULTIFOCAL DISEASE: Yes
HIGH GRADE PIN: Yes - multifocal
EXTRAPROSTATIC EXTENSION: No
PERINEURAL INVASION: Yes
ANGIOLYMPHATIC INVASION: No
SEMINAL VESICLE INVASION: No
SURGICAL MARGIN INVOLVEMENT: All surgical margins free of tumor
LYMPH NODES EXAMINED: 40
LYMPH NODES POSITIVE: 0
T STAGE, PATHOLOGIC: pT2c
N STAGE, PATHOLOGIC: pN0
M STAGE, PATHOLOGIC: pMX
HISTOLOGIC GRADE: G3-4, Poorly differentiated/undifferentiated

*Pur TSS - 70% Acinar
30% Ductal*

*ICD-O-3
Adenocarcinoma, acinar +
ductal 8500/3
Adenocarcinoma, ductal 8500/3
Site: Prostate NOS C61.9*

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form 4.05 ☒

Study Subject ID:		Person ID:	N/A
Study/Site:	TCGA Prostate adenocarcinoma	Age:	N/A
Event:	PathDiscrepancy	Date of Birth:	
Interviewer:		Sex:	M

Tumor Identifier Provided on Initial Case Quality Control Form		Provide the tumor identifier documented on the initial case quality control form for this case.
Pathologic Diagnosis Provided on Initial Pathology Report	invasive prostatic adenocarcinoma, acinar type	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
Histologic features of the sample provided for TCGA, as reflected on the CQCF	NA	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.
Discrepancy between Pathology Report and Case Quality Control Form		
Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form	specimen submitted has a different gleason score	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
Name of TSS Reviewing Pathologist or Biorepository Director	Provide the name of the pathologist who reviewed this case for TCGA.	

GLEASON SCORE OF TISSUE SUBMITTED IS 5+4=9
GLEASON SCORE OF CASE IS 3+5=8

Source: NCI Genomic Data Commons file 3724cc16-a007-40ec-a2d2-6f10d6212849 (TCGA-EJ-A8FP.DA135629-9B8F-460B-8D5E-FC268FEF6561.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).